Somatic mutation profile of tumor specimen MP2PRT-PAVIPL-TMP1-A (aliquot MP2PRT-PAVIPL-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVIPL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,731 days).
Specimen MP2PRT-PAVIPL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ef93981-f4f9-4a69-8a6c-89bd1439a8ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVIPL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVIPL-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/259f673a-2acf-42ab-9609-4ea9f8765a30

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 85/392 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FN1 | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs538117654, COSV60548627; called by muse, mutect2, varscan2
- KDM7A | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 20/668 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); catalogued as rs1465519693; called by muse, mutect2
- NPTXR | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 234/828 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773964723, COSV60728166; called by muse, mutect2, varscan2
- OSBPL8 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs1159758526; called by muse, mutect2, varscan2
- SERPINB12 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200518644, COSV54032923, COSV54035304; called by muse, mutect2, varscan2
- ABCF1 | c.934T>C p.S312P (on ENST00000326195 / NM_001025091.2; = p.S274P on NM_001090.3) | Missense Mutation (SNP) | VAF 189/461 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- AHCTF1 | c.5897G>C p.R1966P (on ENST00000366508; = p.R1940P on NM_015446.5) | Missense Mutation (SNP) | VAF 121/225 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.3453G>T p.M1151I | Missense Mutation (SNP) | VAF 163/466 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SORCS3 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 334/1104 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKH | c.1011C>T p.V337= | Silent (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- HCRTR2 | c.339C>T p.V113= | Silent (SNP) | VAF 159/381 reads (42%) | catalogued as rs200340125, COSV100904291, COSV63793457; called by muse, mutect2, varscan2
- PPFIA2 | c.699C>T p.S233= | Silent (SNP) | VAF 72/330 reads (22%) | catalogued as rs747773198; called by muse, mutect2, varscan2
- RP1L1 | c.213C>T p.R71= | Silent (SNP) | VAF 214/724 reads (30%) | catalogued as rs182267291, COSV100261556; ClinVar: benign; called by muse, mutect2, varscan2
- WAC | c.546A>C p.P182= | Silent (SNP) | VAF 74/251 reads (29%) | called by muse, mutect2, varscan2
- ZNF395 | c.594G>A p.A198= | Silent (SNP) | VAF 144/547 reads (26%) | catalogued as rs780656102; called by muse, mutect2, varscan2
- RORA | c.197-26379G>A | Intron (SNP) | VAF 30/231 reads (13%) | catalogued as rs199937951, COSV55038987; called by muse, mutect2, varscan2
